CPTAC case C3N-03619 — Other and unspecified parts of tongue — Squamous Cell Neoplasms (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Squamous Cell Neoplasms; Primary site: Other and unspecified parts of tongue. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/94badce5-890f-468a-a689-7596a1acbd7d

Demographics
Sex at birth: male; Race: white; Year of birth: 1958; Vital status: Alive; Country of birth: Ukraine.

Diagnoses (1)
1. Squamous cell carcinoma, NOS: ICD-O-3 morphology code: 8070/3; Tissue or organ of origin: Tongue, NOS; Site of resection or biopsy: Tongue, NOS; Age at diagnosis: 59.6 years (21,757 days); Year of diagnosis: 2018; AJCC staging edition: 7th; AJCC clinical M: M0; AJCC pathologic T: T2; AJCC pathologic N: N0; AJCC pathologic M: MX; AJCC pathologic stage: Stage II; Tumor grade: G2; Residual disease: R0; Last known disease status: Tumor free; Days to last known disease status: 97 days; Progression or recurrence: no; Days to last follow up: 97 days; Tumor focality: Unifocal.
   Pathology details: Greatest tumor dimension: 3 cm (a second GDC size field records 12 cm); Lymph node involvement: Negative; Lymph nodes positive: 0; Lymph nodes tested: 4; Lymphatic invasion present: No; Margin status: Uninvolved; Vascular invasion present: No.
   Chemotherapy — whether it was given is not recorded by GDC; Treatment outcome: Complete Response.

Follow-up (1 entry)
- Days to follow up: 97 days; Disease response: Tumor Free.

Other clinical attributes
- Weight: 70 kg; Height: 172 cm; BMI: 23.66; Comorbidities: Pancreatitis.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Smoker; Pack years smoked: 35; Cigarettes per day: 20; Tobacco smoking onset year: 1982; Alcohol history: Yes; Alcohol intensity: Not Heavy Drinker; Exposure duration years: 40.

Biospecimens (4 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3N-03619-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Tongue; Biospecimen laterality: Left; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 0 days; Initial weight: 460 mg; Time between excision and freezing: 10 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3N-03619-22: Section location: Tongue; Percent tumor nuclei: 85; Percent necrosis: 5.
- Sample C3N-03619-06: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Biospecimen anatomic site: Tongue; Biospecimen laterality: Left; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 0 days; Initial weight: 280 mg; Time between excision and freezing: 11 minutes; Method of sample procurement: Surgical Resection; Diagnosis pathologically confirmed: Yes.
- Sample C3N-03619-12: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Tongue; Biospecimen laterality: Left; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 0 days; Time between excision and freezing: 10 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
- Sample C3N-03619-71: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: 0 days; Method of sample procurement: Blood Draw.
